Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6952, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6952-01A (Primary Tumor).

DIAGNOSIS

- (A) TOTAL ORAL GLOSSECTOMY:
INVASIVE WELL DIFFERENTIATED SQUAMOUS CARCINOMA OF THE TONGUE WITH
EXTENSIVE PERINEURAL INVASION PRESENT AT THE SKELETAL MUSCLE
RESECTION MARGIN, ALL MUCOSAL MARGINS NEGATIVE.
- (B) BILATERAL NECK DISSECTION:
METASTATIC SQUAMOUS CARCINOMA IN 1 OF 2 RIGHT MIDJUGULAR NODES.
METASTATIC SQUAMOUS CARCINOMA IN 1 OF 7 RIGHT LOWER JUGULAR LYMPH
NODES.
METASTATIC SQUAMOUS CARCINOMA IN 1 RIGHT SUPRACLAVICULAR LYMPH NODE.
Eleven additional right neck lymph nodes, negative for tumor (2
submental, 4 subdigastric, 5 lower posterior cervical).
Twenty-two left neck lymph nodes, negative for tumor (2 submental,
2 mid jugular, 10, mid posterior cervical, 6 lower posterior
cervical and 2 supraclavicular).
- (C) TEETH:
Multiple teeth, gross diagnosis only.

COMMENT

The carcinoma measures 4.0 x 3.0 x 2.0 cm. It is involving the
entire thickness of the tongue. The tumor has extensive perineural invasion
present at the skeletal muscle resection margin.

The largest metastasis measures 1.5 cm and is present in a right lower
jugular lymph node. The tumor involves 90% of the lymph node parenchyma,
however, unequivocal extranodal extension is not identified.

SPECIMEN

- (A) TOTAL ORAL GLOSSECTOMY:
(B) BILATERAL NECK DISSECTION:
(C) TEETH:

Source: NCI Genomic Data Commons file 17267d9e-0f73-4775-9387-e4d0f54a7546 (TCGA-CV-6952.D61A7719-AFF0-489E-B0F5-F41751829489.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).